Gene-level copy-number profile of tumor specimen ALCH-B3FM-TTP1-A from ALCHEMIST case ALCH-B3FM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.8 years (28,409 days).
Specimen ALCH-B3FM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c3a0072-6143-48ea-8955-0ad50ee06129.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/f752b51a-b970-459e-afd9-ca5ae4876868

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 26; copy number 2: 502; copy number 3: 441; copy number 4: 38,739; copy number 5: 1,842; copy number 6: 9,204; copy number 7: 913; copy number 8: 6,137; copy number 9: 522; copy number 10: 1; copy number 11: 55; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,391,810, 1 gene: AC139453.2.
- chr13:37,854,852–37,854,970, 1 gene (within-gene range 0–4): RNA5SP26.
- chr17:22,233,926–22,266,392, 1 gene: LINC02002.
- chr17:40,012,226–40,017,813, 2 genes: AC090844.3, CSF3.
- chr17:40,026,332–40,027,645, 2 genes (within-gene range 0–4): MIR6884, SNORD124.
- chr19:17,871,273–17,871,705, 1 gene: AC005796.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 507 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,900,493, 70 genes, copy number 9 (broad region; genes not listed).
- chr5:9,035,033–9,546,075, 2 genes, copy number 9 (within-gene range 6–9): SEMA5A, MIR4636.
- chr5:63,022,919–63,023,489, 1 gene, copy number 9: AC113420.1.
- chr6:32,517,353–32,530,287, 1 gene, copy number 9: HLA-DRB5.
- chr7:37,032–2,394,131, 64 genes, copy number 9 (broad region; genes not listed).
- chr7:44,503,773–44,511,332, 2 genes, copy number 13: RNU6-1097P, AC004938.1.
- chr14:22,066,016–22,492,907, 53 genes, copy number 11: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47.
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr14:102,592,649–106,879,812, 311 genes, copy number 9 (broad region; genes not listed).
- chr16:2,339,150–2,426,699, 1 gene, copy number 11 (within-gene range 6–11): ABCA17P.
- chr16:28,111,173–28,111,647, 1 gene, copy number 10: TPRKBP2.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
